Somatic mutation profile of tumor specimen TCGA-CN-6022-01A (aliquot TCGA-CN-6022-01A-21D-1683-08) from TCGA case TCGA-CN-6022, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 49.2 years (17,971 days).
Specimen TCGA-CN-6022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c36703a5-0bd4-4dd3-a02c-79f2f9e0429c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6022-10A (Blood Derived Normal), aliquot TCGA-CN-6022-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b986e09-6e7e-44f4-9e2b-e982ccd725a6

The open-access MAF lists 78 somatic variants for this specimen: 57 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 20, Splice Site 3, Nonsense Mutation 3, Splice Region 2, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.782+1G>A p.X261_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 22/75 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ABCA6 | c.3196G>A p.V1066I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs766759180, COSV52641225; called by muse, mutect2, varscan2
- APBA2 | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV101258216; called by muse, mutect2, varscan2
- ARL11 | c.19A>G p.R7G | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV99949235; called by muse, mutect2, varscan2
- BTNL2 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.303); catalogued as COSV100896214; called by muse, mutect2, varscan2
- CCDC28A | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs749487351, COSV100236651; called by muse, mutect2, varscan2
- CEP76 | c.521-1G>A p.X174_splice | Splice Site (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100043003; called by muse, mutect2, varscan2
- CLBA1 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1401251035, COSV66348230; called by muse, mutect2, varscan2
- COL4A1 | c.2941G>C p.G981R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011616, COSV65432063; called by muse, mutect2, varscan2
- COX15 | c.1147C>G p.L383V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV99187661; called by muse, mutect2, varscan2
- CUL1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57390285; called by muse, mutect2, varscan2
- DEPDC1B | c.302G>C p.R101P | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV54011229, COSV99409896; called by muse, mutect2, varscan2
- EPHA10 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs200657467; called by muse, mutect2, varscan2
- FCRLA | c.375G>C p.W125C (on ENST00000367959; = p.W102C on NM_032738.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52688532, COSV99376663; called by mutect2, varscan2
- FMN2 | c.5014T>A p.F1672I | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100147234; called by muse, mutect2, varscan2
- GRIN2A | c.4226C>T p.A1409V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV58044425; called by muse, mutect2, varscan2
- HNRNPUL1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99647631; called by muse, mutect2, varscan2
- HYDIN | c.9256G>T p.V3086L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV99993744; called by muse, mutect2, varscan2
- ITGAE | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV99561572; called by muse, mutect2, varscan2
- KATNA1 | c.921T>G p.I307M | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.812); catalogued as COSV59502110, COSV59503212; called by muse, mutect2, varscan2
- KIF6 | c.1784G>C p.S595T | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as COSV99760830; called by muse, mutect2, varscan2
- KLHL25 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.563); catalogued as rs768561009, COSV100563741; called by muse, mutect2, varscan2
- KMT2D | c.4945G>T p.E1649* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as COSV56461051; called by muse, mutect2, varscan2
- LAMP3 | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV55615690; called by muse, mutect2, varscan2
- LIG4 | c.1885A>T p.K629* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as COSV63597481; called by muse, mutect2, varscan2
- LIN54 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100465051; called by muse, mutect2, varscan2
- LSS | c.1011G>A p.P337= | Splice Region (SNP) | VAF 14/102 reads (14%) | catalogued as rs759946114, COSV100711060, COSV100711091; called by muse, mutect2
- MRPS15 | c.299A>G p.K100R | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100118287; called by muse, varscan2
- NDC1 | c.1050C>G p.F350L | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52334338; called by muse, mutect2, varscan2
- OPN4 | c.1418G>T p.S473I | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs1373595368, COSV53945490; called by muse, mutect2, varscan2
- OR2AK2 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.658); catalogued as COSV100824345; called by muse, mutect2, varscan2
- OR8H1 | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs765451788, COSV100477372; called by muse, mutect2, varscan2
- PCNT | c.9752C>G p.P3251R | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs138097697, COSV100856056, COSV64026894; called by muse, mutect2, varscan2
- PLXND1 | c.5245G>A p.E1749K | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV60714214; called by muse, mutect2, varscan2
- PNPLA4 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66854279; called by muse, mutect2
- PRKACA | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100432307; called by muse, mutect2, varscan2
- PTPRC | c.2822C>T p.P941L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs577595945, COSV100723217, COSV61421372; called by muse, mutect2
- QRICH2 | c.2725C>T p.Q909* | Nonsense Mutation (SNP) | VAF 14/150 reads (9%) | catalogued as COSV99429738; called by muse, mutect2, varscan2
- RANBP2 | c.6275C>T p.T2092M | Missense Mutation (SNP) | VAF 70/472 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs760931362, COSV51701084; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFPL3 | c.817G>A p.V273I (on ENST00000249007 / NM_001098535.1; = p.V244I on NM_006604.2) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs758019654, COSV99967288; called by muse, mutect2, varscan2
- ROCK1 | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101296630; called by muse, mutect2, varscan2
- RRAGC | c.757-2A>G p.X253_splice | Splice Site (SNP) | VAF 17/90 reads (19%) | catalogued as COSV100883864; called by muse, mutect2, varscan2
- RYR1 | c.10168G>T p.G3390C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV100617047, COSV62096149; called by muse, mutect2, varscan2
- SCUBE3 | c.2601A>G p.S867= | Splice Region (SNP) | VAF 99/334 reads (30%) | catalogued as COSV99235265; called by muse, mutect2, varscan2
- SEC31B | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV100649140; called by muse, mutect2, varscan2
- SPAG6 | c.1285C>G p.L429V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV100510512; called by muse, mutect2, varscan2
- SPTBN1 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV61690646; called by muse, mutect2
- ST6GALNAC5 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 32/232 reads (14%) | PolyPhen probably damaging (0.995); catalogued as COSV100603102; called by muse, mutect2, varscan2
- SUSD6 | c.584G>C p.R195T | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100713520, COSV61365068; called by muse, mutect2, varscan2
- YY2 | c.871G>C p.A291P | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100810856; called by muse, mutect2, varscan2
- ZBTB22 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as rs1270348600, COSV56471459; called by muse, mutect2, varscan2
- ZFHX4 | c.287T>G p.M96R | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV99268031; called by muse, mutect2, varscan2
- ZNF292 | c.5335G>T p.G1779C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.319); catalogued as COSV100371569, COSV60542479; called by muse, mutect2, varscan2
- ZNF80 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as rs759825872, COSV57361014; called by mutect2, varscan2
- ZSCAN2 | c.1556T>C p.V519A | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV57572127; called by muse, mutect2, varscan2
- CTNNA1 | c.355_357dup p.V119dup | In Frame Ins (INS) | VAF 13/87 reads (15%) | called by mutect2, pindel, varscan2
- AFG1L | c.1347C>T p.T449= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs776358723, COSV64556752; called by muse, mutect2, varscan2
- ALKBH4 | c.432G>C p.G144= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV99479567, COSV99479573; called by muse, mutect2, varscan2
- DNAH10 | c.1110C>T p.I370= (on ENST00000409039; = p.I309= on NM_207437.3) | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV68996837, COSV69000072; called by muse, mutect2, varscan2
- DNAH10 | c.2346G>A p.T782= (on ENST00000409039; = p.T721= on NM_207437.3) | Silent (SNP) | VAF 74/244 reads (30%) | catalogued as rs780406596, COSV68995231; called by muse, mutect2, varscan2
- EFHC1 | c.567C>T p.F189= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV100932157; called by muse, mutect2
- NCOA1 | c.1591C>A p.R531= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV99946961, COSV99947121; called by muse, mutect2, varscan2
- OVOL2 | c.348G>T p.S116= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs769786984, COSV99602539, COSV99602588; called by muse, mutect2, varscan2
- P2RX7 | c.765G>A p.E255= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV99947817; called by muse, mutect2, varscan2
- PGAP6 | c.1071G>A p.T357= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as rs1242942259, COSV51738643; called by muse, mutect2, varscan2
- PIWIL1 | c.183G>A p.K61= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV55348995; called by muse, mutect2
- PPFIA3 | c.174G>A p.L58= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs761995003, COSV61951046; called by muse, mutect2, varscan2
- PTP4A3 | c.513C>T p.C171= (on ENST00000329397; = p.C146= on NM_007079.3) | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as rs150126504; called by muse, mutect2, varscan2
- RAD17 | c.598C>T p.L200= (on ENST00000380774 / NM_133339.2; = p.L189= on NM_002873.1) | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs1396927862, COSV51456658, COSV99281784; called by muse, mutect2, varscan2
- RGS12 | c.4026G>A p.L1342= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV100123376; called by muse, mutect2, varscan2
- SETD9 | c.834T>G p.L278= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs374889494, COSV53650752; called by muse, mutect2, varscan2
- SLC26A1 | c.2034C>T p.L678= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99926486; called by muse, mutect2
- SYNJ2 | c.990G>A p.T330= | Silent (SNP) | VAF 44/370 reads (12%) | catalogued as rs750486579, COSV62896419; called by muse, mutect2, varscan2
- TRAFD1 | c.300C>G p.L100= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV57503571, COSV99987004; called by muse, mutect2, varscan2
- TRHDE | c.420C>T p.R140= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99672655; called by muse, mutect2, varscan2
- UBL7 | c.1041C>T p.D347= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV100795466; called by muse, mutect2, varscan2
- CTBP2 | c.58+11403C>A | Intron (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100456943; called by muse, mutect2, varscan2
